Surgical pathology report (de-identified scan), TCGA case TCGA-RR-A6KA, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RR-A6KA-01A (Primary Tumor).

Pathology Report

Date of Surgery:

Diagnosis:

Right frontal glioblastoma

Microscopic Description:

Sections demonstrate a markedly hypercellular, diffusely infiltrating astrocytic neoplasm along with abundant necrosis. Microvascular proliferation is seen. The tumor cells demonstrate severe atypia. Scattered mitotic figures are seen.

ICD-O-3

Glioblastoma multiforme
94401/3

Site *Brain, frontal*
lobe C71.1

6/28/13

Source: NCI Genomic Data Commons file e4617f27-30eb-4de0-8814-b220bf01c1ca (TCGA-RR-A6KA.F58558E1-9BB7-4991-9CDD-6C18DCB448E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).